Surgical pathology report (de-identified scan), TCGA case TCGA-N6-A4VD, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of Pittsburgh, specimen TCGA-N6-A4VD-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: UTERUS WITH CERVIX AND BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (110 GRAMS) -
A. MIXED MALIGNANT MÜLLERIAN TUMOR (CARCINOSARCOMA).
B. TUMOR MEASURES 5.5 CM.
C. TUMOR INVADES THROUGH THE POSTERIOR MYOMETRIUM (100%), AND FORMS A NODULE ON THE SEROSAL SURFACE.
D. NO DEFINITE LYMPHOVASCULAR INVASION IS IDENTIFIED.
E. LOWER UTERINE SEGMENT MARGIN IS NEGATIVE FOR INVOLVEMENT BY TUMOR; CERVICAL TISSUE IS NOT SEEN IN THE SPECIMEN GROSSLY OR MICROSCOPICALLY.
F. LEFT AND RIGHT FALLOPIAN TUBES ARE NEGATIVE FOR TUMOR.
G. LEFT AND RIGHT OVARIES ARE NEGATIVE FOR TUMOR.
H. RIGHT OVARY WITH INFLAMMATORY ADHESIONS
I. RIGHT FALLOPIAN TUBE WITH SEROSAL FOREIGN BODY GIANT CELL REACTION TO POLARIZABLE MATERIAL AND ADHERENT NODULAR AGGREGATE OF INFLAMMATORY CELLS WITH GRANULATION-TYPE INFLAMMATORY TISSUE.
J. PATHOLOGIC STAGE: pT3a pN0 pMX (FIGO stage IIIA).

PART 2: RIGHT COMMON ILIAC LYMPH NODE, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

PART 3: LEFT EXTERNAL ILIAC LYMPH NODE, BIOPSY -
ONE LYMPH NODE WITH SMALL GRANULOMA FORMATION, NEGATIVE FOR TUMOR (0/1) (see comment).

COMMENT:

The tumor is biphasic, with a high grade serous carcinoma component and a high grade endometrial stromal sarcoma component.

Immunostains were attempted on Part 3 but the granulomas were not present on the stained slides (AE1/3 was otherwise negative; CD68 demonstrated numerous histiocytes). Stains to rule out fungal and acid-fast organisms are pending and will be reported separately.

Please cross-refer the pelvic wash specimen [REDACTED] which was negative for malignant cells.

MICROSCOPIC:

Microscopic examination substantiates the above diagnoses.

Antibody/Antigen	Result
AE1/AE3	negative
CD68	positive staining for histiocytes

Utilizing formalin-fixed (8-96 hour range), paraffin embedded tissue, immunohistology is performed with the following selected antibodies and designated antibody clone(s), directed against the following antigenic target(s), with adequate positive and negative internal and external controls. Antibodies are optimized appropriate for fixation times.

ANTIBODY	CLONE	TARGET ANTIGEN	VENDOR
AE1/AE3	AE1/AE3	carcinomas	
CD68	KP-1	macrophages	

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Carcinosarcoma (malignant mixed mesodermal tumor)

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Poorly differentiated (FIGO 3)

TUMOR SIZE: Maximum dimension: 5.5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 0 %, Posterior endomyometrium: 100 %

DEPTH OF INVASION:** Into serosa

ANGIOLYMPHATIC INVASION: No

LYMPH NODES POSITIVE: Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 2

T STAGE, PATHOLOGIC: pT3a

N STAGE, PATHOLOGIC: pN0

M STAGE, PATHOLOGIC: pMX

FIGO STAGE: IIIA

ICD-O-3
Carcinosarcoma, mixed Müllerian
Tumor, malignant 8950/3
Site: Corpus Uteri, Endometrium
C54.1

QW 3/28/13

ICD-O Discrepancy		☒
Time Discrepancy History		☒
Out-of-Sync Primary Notes		☒
Case is Discrep	☒	

Source: NCI Genomic Data Commons file e9bbfd71-b5b1-46f8-b469-cf4ef204fbef (TCGA-N6-A4VD.B1D9BFB6-3943-457E-ACBC-89504A5CD7E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).